Somatic mutation profile of tumor specimen 0DJVPM from CCDI case PBBWYT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.5 years (3,469 days).
Specimen 0DJVPM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1a2e09b-3d9d-46e8-90ac-5c7d46371094.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVP8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71c977a3-3323-44a8-ae4a-2aa6dc988e35

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 64/1504 reads (4%) | catalogued as COSV59989381; called by muse, mutect2
- NAV2 | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 143/1405 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.172); called by mutect2, varscan2
- OR51I2 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 46/1703 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- POLR1F | c.953A>G p.E318G | Missense Mutation (SNP) | VAF 669/1499 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 38/1130 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- ABCB5 | c.639G>A p.T213= | Silent (SNP) | VAF 578/1322 reads (44%) | catalogued as rs751089247, COSV51717378; called by muse, varscan2
- CCDC27 | c.876C>T p.D292= | Silent (SNP) | VAF 276/618 reads (45%) | catalogued as rs375200194; called by muse, mutect2, varscan2
- CENPU | c.1200C>T p.A400= | Silent (SNP) | VAF 665/1518 reads (44%) | catalogued as rs780421856, COSV55658494, COSV55659176; called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 38/1109 reads (3%) | catalogued as rs1267156464; called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 6/118 reads (5%) | catalogued as COSV55814242; called by muse, mutect2
